TARGET case TARGET-10-PARFHH — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8c731b4c-61d5-5292-aae0-df0535a0dbbb

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 5 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 5.7 years (2,073 days); Year of diagnosis: 2007; Days to last follow up: 3,216 days (8.8 years).
   Treatment given: Protocol identifier: AALL0331.

Follow-up (1 entry)
- Days to follow up: 3,216 days (8.8 years); Event-free: no event (relapse, second malignancy or death) recorded through day 3,216; Year of follow up: 2016.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Positive.
- KMT2A rearrangement (FISH): Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 7.58 ×10³/µL.
- Day 8: Bone Marrow blast count 12%; Minimal Residual Disease (Flow Cytometry) 7.8%.
- Day 15: Bone Marrow blast count 0%.
- Day 29: Bone Marrow blast count 1%; Minimal Residual Disease (Flow Cytometry) 0.14%.
- Day 43: Bone Marrow blast count 1%.

Biospecimens (2 samples)
- Sample TARGET-10-PARFHH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARFHH-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_Blast_Data_20230727.xlsx, for sample TARGET-10-PARFHH-09A-01D:
- Blast %: 87

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Validation_20230727.xlsx:
- Overall Survival Time in Days: 3216
- WBC at Diagnosis: 7.58
- CNS Status at Diagnosis: CNS 1
- Testicular Involvement: No
- MRD Day 8: 7.8
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0.14
- MRD Day 29 Sensitivity: 0.01
- MRD End Consolidation Sensitivity: 0.01
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Positive
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 12
- BMA Blasts Day 15: 0
- BMA Blasts Day 29: 1
- BMA Blasts Day 43: 1
- Down Syndrome: No
- DNA Index: 1
- Alternate Therapy: Chemotherapy
- Cell of Origin: B Cell ALL
